Somatic mutation profile of tumor specimen 0DWYWH from CCDI case PBCNTM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Craniopharyngioma, adamantinomatous; Tissue or organ of origin: Craniopharyngeal duct; Age at diagnosis: 13.2 years (4,837 days).
Specimen 0DWYWH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f5bc449-d70a-449b-a2cd-c97f675f5353.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWYUM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee0b0fcd-9845-4ec1-89da-4a187cdfbaf0

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPIPB11 | c.3118A>C p.T1040P | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.006); catalogued as rs191545623; called by muse, varscan2
